Somatic mutation profile of tumor specimen TCGA-19-0957-02A (aliquot TCGA-19-0957-02A-11D-2280-08) from TCGA case TCGA-19-0957, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.5 years (17,714 days).
Specimen TCGA-19-0957-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb44dc1a-18d0-4726-9a6c-5392f757acb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-0957-10A (Blood Derived Normal), aliquot TCGA-19-0957-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8de11478-834a-42f0-ab0b-090d06b12b8d

The open-access MAF lists 126 somatic variants for this specimen: 88 protein-altering or splice-affecting, 36 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 36, Splice Site 5, Nonsense Mutation 4, Frame Shift Del 2, Splice Region 2, Frame Shift Ins 1, Intron 1, In Frame Ins 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.1026+1G>C p.X342_splice | Splice Site (SNP) | VAF 15/40 reads (38%) | hotspot (GDC flag); catalogued as rs786201041, CS043794, CS110216, COSV64288702, COSV64289135, COSV64293873; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TRPV6 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 46/302 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1281361203, COSV63892531; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as CM157252; called by muse, mutect2
- AC093525.2 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 36/159 reads (23%) | PolyPhen benign (0.003); catalogued as COSV53552173, COSV99566089; called by muse, mutect2, varscan2
- ACAD10 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs575221081, COSV58154089; called by muse, mutect2, varscan2
- ADA2 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs777683953, COSV52832469; called by muse, mutect2, varscan2
- AL121899.2 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs781217795, COSV101198618; called by muse, mutect2, varscan2
- AMPD3 | c.422C>T p.A141V (on ENST00000396553 / NM_001025389.2; = p.A150V on NM_000480.3) | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV67333145; called by muse, mutect2, varscan2
- APOL1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 22/125 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1334345255, COSV100046306; called by muse, mutect2, varscan2
- ARID1A | c.2666G>A p.G889D | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.878); catalogued as COSV61378279, COSV61389939; called by muse, mutect2, varscan2
- BPTF | c.4922C>T p.T1641M | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs1017462944, COSV100073898; called by muse, mutect2, varscan2
- CALD1 | c.2338G>A p.E780K (on ENST00000361675 / NM_033138.4; = p.E525K on NM_004342.7) | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407090426; called by muse, mutect2
- CDH11 | c.1655G>A p.G552D | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as COSV99219496; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2414G>T p.G805V | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV62572755, COSV62578333; called by muse, mutect2
- CLCNKB | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 46/137 reads (34%) | catalogued as COSV100990435; called by muse, mutect2, varscan2
- COP1 | c.2167G>T p.G723C | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99056663; called by muse, mutect2, varscan2
- CYP4A22 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 86/293 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.075); catalogued as rs536116490, COSV99595272; called by muse, mutect2, varscan2
- EHD4 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as rs554166246, COSV99588267; called by muse, mutect2, varscan2
- FAM124A | c.790C>T p.R264C (on ENST00000322475 / NM_001242312.2; = p.R300C on NM_145019.4) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54476071; called by muse, mutect2, varscan2
- FAT2 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs574821566; called by muse, mutect2, varscan2
- FRY | c.7205C>T p.S2402F | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV100968645; called by muse, mutect2
- FSIP2 | c.18664G>A p.E6222K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as COSV100554465; called by muse, mutect2, varscan2
- FUBP1 | c.191A>G p.K64R | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99629441; called by muse, mutect2, varscan2
- IGSF9 | c.1546G>A p.V516M (on ENST00000368094 / NM_001135050.2; = p.V500M on NM_020789.4) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs771632078, COSV63643036; called by muse, mutect2, varscan2
- IL11RA | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52405582; called by muse, mutect2, varscan2
- LARS1 | c.2866C>T p.R956C (on ENST00000394434 / NM_020117.11; = p.R929C on NM_016460.3) | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as rs200546271; called by muse, mutect2, varscan2
- MAGEE2 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs1010895374; called by muse, mutect2, varscan2
- MAN2B2 | c.2410G>A p.D804N | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.034); catalogued as COSV53454124; called by muse, mutect2
- MRPL4 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs372183483; called by muse, mutect2, varscan2
- MTARC2 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV100831025; called by muse, mutect2, varscan2
- MYH13 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV52822897; called by muse, mutect2, varscan2
- NCKAP1L | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 113/289 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs752125351, COSV53203384; called by muse, mutect2, varscan2
- NDST1 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.205); catalogued as rs1291890754, COSV55788566; called by muse, mutect2, varscan2
- NUP133 | c.2297C>T p.T766M | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs537234819, COSV54570575; called by muse, mutect2, varscan2
- OPRK1 | c.434G>A p.S145N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55573357; called by muse, mutect2, varscan2
- OR8K1 | c.75C>A p.D25E | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as rs769004561, COSV54401922; called by muse, mutect2, varscan2
- PCDH11X | c.3146C>T p.S1049F | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV53455566; called by muse, mutect2, varscan2
- PDXDC1 | c.686T>C p.I229T | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.16); catalogued as rs780031901, COSV100363382; called by muse, mutect2
- PGK2 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100505644; called by muse, mutect2, varscan2
- PIK3CG | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV100783093; called by muse, mutect2, varscan2
- PIP4K2C | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs774720885, COSV61606343, COSV61606568; called by muse, mutect2, varscan2
- PROC | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 17/227 reads (7%) | catalogued as CM155869; called by muse, mutect2
- PTCH1 | c.3904C>T p.P1302S | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs747093389, COSV100109660; called by muse, varscan2
- RGS22 | c.538G>C p.A180P | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100693673; called by muse, mutect2, varscan2
- RIPK4 | c.2105G>A p.R702K (on ENST00000352483; = p.R654K on NM_020639.3) | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.431); catalogued as COSV100205289; called by muse, mutect2, varscan2
- RPLP0 | c.27G>A p.W9* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as COSV57215636; called by muse, mutect2
- SH3PXD2B | c.1627C>G p.R543G | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); catalogued as COSV100288400; called by muse, mutect2, varscan2
- SLC1A6 | c.1097C>T p.T366I | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs770752701; called by muse, mutect2, varscan2
- SLC6A12 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs778209309, COSV100675213; called by muse, mutect2, varscan2
- TBX6 | c.849C>A p.D283E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV99661764; called by muse, mutect2, varscan2
- TCEAL5 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV101013171; called by muse, mutect2, varscan2
- TMEM132D | c.709G>T p.G237W | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101399216; called by muse, mutect2, varscan2
- TRIM56 | c.1527del p.I510Sfs*22 | Frame Shift Del (DEL) | VAF 49/276 reads (18%) | catalogued as COSV60160979; called by mutect2, pindel, varscan2
- ZNF804B | c.1037G>T p.R346I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV100305546; called by muse, mutect2, varscan2
- ACTG1 | c.1097G>A p.G366D | Missense Mutation (SNP) | VAF 21/285 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADH1C | c.334T>C p.C112R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP7 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- ANKRD33 | c.136G>A p.V46M (on ENST00000340970 / NM_001304459.2; = p.V181M on NM_182608.4) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); called by muse, mutect2
- ATP8B2 | c.1145T>C p.I382T (on ENST00000672630; = p.I349T on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- BTN2A2 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C1orf54 | c.255_262del p.D86Efs*13 | Frame Shift Del (DEL) | VAF 21/117 reads (18%) | called by mutect2, pindel, varscan2
- CARS2 | c.786-1G>A p.X262_splice | Splice Site (SNP) | VAF 11/90 reads (12%) | called by muse, mutect2, varscan2
- CCDC8 | c.1349G>A p.G450D | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.469); called by muse, mutect2
- COL15A1 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CPXM2 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 46/316 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND1B | c.126+1G>A p.X42_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- ECRG4 | c.104dup p.L36Afs*13 | Frame Shift Ins (INS) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- ENOSF1 | c.798-12_808del p.X266_splice (on ENST00000340116 / NM_001354066.2; = p.X218_splice on NM_017512.7 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 22/145 reads (15%) | called by mutect2, pindel
- GHDC | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GMIP | c.2711C>G p.P904R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- GUF1 | c.921G>C p.E307D | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- HMCN1 | c.11597C>T p.P3866L | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JPH3 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 18/217 reads (8%) | called by muse, mutect2
- LGR5 | c.2620T>C p.S874P | Missense Mutation (SNP) | VAF 736/2345 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LIMK2 | c.512G>A p.S171N | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- MED12 | c.2226G>A p.Q742= | Splice Region (SNP) | VAF 26/234 reads (11%) | called by muse, mutect2, varscan2
- MINDY4 | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOVA1 | c.896_898dup p.A299_F300insS | In Frame Ins (INS) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- PPIP5K2 | c.3492T>A p.I1164= (on ENST00000358359 / NM_001276277.3; = p.I1143= on NM_015216.5 and 5 other RefSeq transcripts) | Splice Region (SNP) | VAF 27/115 reads (23%) | called by muse, mutect2, varscan2
- RALGPS2 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBM19 | c.1076G>C p.G359A | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RFC5 | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMYD5 | c.184A>T p.N62Y | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SULT1A2 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF1B | c.416T>G p.L139R | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- THOC6 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UROC1 | c.257+1G>A p.X86_splice | Splice Site (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- WASHC2A | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, varscan2
- ABCB8 | c.1350C>T p.A450= (on ENST00000297504 / NM_001282291.2; = p.A433= on NM_007188.5) | Silent (SNP) | VAF 30/310 reads (10%) | catalogued as rs1346315126; called by muse, mutect2
- B4GALNT3 | c.2541G>A p.Q847= | Silent (SNP) | VAF 26/184 reads (14%) | called by muse, mutect2, varscan2
- C4BPA | c.1761C>T p.S587= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs762923928, COSV100891174; called by muse, mutect2, varscan2
- CRYZL1 | c.171G>A p.K57= | Silent (SNP) | VAF 13/171 reads (8%) | called by muse, mutect2
- CXorf56 | c.165G>A p.R55= | Silent (SNP) | VAF 13/336 reads (4%) | called by muse, mutect2
- DBH | c.1551C>T p.H517= | Silent (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- DMRTC2 | c.714T>C p.P238= | Silent (SNP) | VAF 9/242 reads (4%) | catalogued as rs782531999; called by muse, mutect2
- DOP1A | c.744C>T p.D248= | Silent (SNP) | VAF 12/137 reads (9%) | called by muse, mutect2
- DYRK4 | c.394C>T p.L132= | Silent (SNP) | VAF 18/134 reads (13%) | called by muse, mutect2, varscan2
- EXOSC2 | c.723C>T p.I241= | Silent (SNP) | VAF 19/203 reads (9%) | called by muse, mutect2
- FAM83B | c.2757G>A p.T919= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as rs746397400, COSV100174878; called by muse, mutect2, varscan2
- HECTD2 | c.402C>T p.D134= | Silent (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
- IL4I1 | c.817C>T p.L273= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- KCNH2 | c.1041C>T p.P347= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs545444296; called by muse, mutect2
- LILRA2 | c.852T>C p.P284= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as rs1281410212, COSV99253105; called by muse, mutect2, varscan2
- MYO16 | c.645C>T p.V215= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as COSV99193485; called by muse, mutect2
- NAA11 | c.147C>T p.D49= | Silent (SNP) | VAF 66/225 reads (29%) | catalogued as COSV54516092; called by muse, mutect2, varscan2
- NSMCE1 | c.555C>T p.P185= | Silent (SNP) | VAF 74/280 reads (26%) | catalogued as rs375663140; called by muse, mutect2, varscan2
- PEX6 | c.1899G>A p.G633= | Silent (SNP) | VAF 40/296 reads (14%) | catalogued as rs767279536; called by muse, mutect2, varscan2
- PLCB3 | c.1374C>T p.D458= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- POPDC3 | c.507C>T p.G169= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs774623615, COSV54644674; called by muse, mutect2, varscan2
- PRKAA2 | c.723C>T p.V241= | Silent (SNP) | VAF 113/460 reads (25%) | catalogued as rs753291156, COSV100983028; called by muse, mutect2, varscan2
- REV1 | c.669C>T p.A223= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV99301345; called by muse, mutect2, varscan2
- SDK1 | c.5922C>T p.Y1974= | Silent (SNP) | VAF 40/206 reads (19%) | catalogued as rs377413537; called by muse, mutect2, varscan2
- SEMA3G | c.1611C>T p.D537= | Silent (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- SFN | c.381C>T p.Y127= | Silent (SNP) | VAF 11/115 reads (10%) | called by muse, mutect2
- SIM1 | c.465G>A p.E155= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV53496684; called by muse, mutect2
- SLC5A11 | c.645G>A p.A215= | Silent (SNP) | VAF 90/320 reads (28%) | catalogued as rs759987745, COSV61743396; called by muse, mutect2, varscan2
- SNX18 | c.1128G>A p.Q376= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- SPOCD1 | c.42C>T p.D14= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as rs757463051; called by muse, mutect2, varscan2
- STYK1 | c.84C>T p.I28= | Silent (SNP) | VAF 73/255 reads (29%) | catalogued as rs769680668, COSV99312148; called by muse, mutect2, varscan2
- TGM1 | c.2038C>T p.L680= | Silent (SNP) | VAF 23/205 reads (11%) | catalogued as COSV99253086; called by muse, mutect2, varscan2
- TRIOBP | c.2394G>A p.R798= | Silent (SNP) | VAF 20/156 reads (13%) | called by muse, mutect2, varscan2
- WDR11 | c.2109G>A p.R703= | Silent (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- ZMAT4 | c.297C>T p.H99= | Silent (SNP) | VAF 42/165 reads (25%) | catalogued as rs189553545, COSV52708095, COSV52715861; called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.633C>T p.A211= | Silent (SNP) | VAF 28/91 reads (31%) | called by muse, mutect2, varscan2
- SLIT2 | c.1463-605G>A | Intron (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2, varscan2
- SNORD115-22 | n.33A>G | RNA (SNP) | VAF 63/500 reads (13%) | called by muse, mutect2, varscan2
